Somatic mutation profile of tumor specimen TCGA-CJ-5677-01A (aliquot TCGA-CJ-5677-01A-11D-1534-10) from TCGA case TCGA-CJ-5677, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 54.3 years (19,849 days).
Specimen TCGA-CJ-5677-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bca711e-f3a7-49d5-8826-2f21d66a793d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5677-11A (Solid Tissue Normal), aliquot TCGA-CJ-5677-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8aff9c08-2d52-4759-8455-f0a7d1edd655

The open-access MAF lists 81 somatic variants for this specimen: 63 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 17, Frame Shift Del 9, Nonsense Mutation 3, Splice Site 2, Splice Region 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 21/117 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VHL | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 56/144 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1559429613, CM941380, COSV56544074, COSV56552085; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.2102G>A p.W701* | Nonsense Mutation (SNP) | VAF 23/373 reads (6%) | catalogued as COSV50732807; called by muse, mutect2
- ADGRG2 | c.510+1G>A p.X170_splice (on ENST00000379869 / NM_001079858.3; = p.X167_splice on NM_005756.4) | Splice Site (SNP) | VAF 61/942 reads (6%) | catalogued as COSV61337650; called by muse, mutect2
- AKAP4 | c.2137A>T p.K713* | Nonsense Mutation (SNP) | VAF 56/201 reads (28%) | catalogued as COSV62073746; called by muse, mutect2, varscan2
- ANKIB1 | c.11C>A p.T4K | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.546); catalogued as COSV56058749; called by muse, mutect2, varscan2
- ARHGEF18 | c.809G>A p.R270H (on ENST00000359920 / NM_001130955.2; = p.R166H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560092117, COSV60467149; called by muse, mutect2, varscan2
- ATP8B2 | c.1267T>G p.F423V (on ENST00000672630; = p.F390V on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59244796; called by muse, mutect2, varscan2
- ATXN2L | c.2251C>A p.L751I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV100293818; called by muse, varscan2
- C19orf47 | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63508473; called by muse, mutect2, varscan2
- C1orf159 | c.499T>G p.F167V (on ENST00000379339 / NM_001330306.2; = p.F131V on NM_017891.5) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV53879656; called by muse, mutect2, varscan2
- CARF | c.476T>G p.V159G | Missense Mutation (SNP) | VAF 189/513 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as COSV57546575; called by muse, mutect2, varscan2
- CEP170 | c.3186G>C p.E1062D | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.98); catalogued as COSV60506292; called by muse, varscan2
- CHRM3 | c.50G>C p.S17T | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as rs1244235649, COSV55080937; called by muse, mutect2, varscan2
- CIP2A | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV55417210, COSV55418843; called by muse, mutect2, varscan2
- CNBD1 | c.1049T>A p.V350E | Missense Mutation (SNP) | VAF 41/891 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072466, COSV73073193; called by muse, mutect2
- COL7A1 | c.2349G>T p.Q783H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV60391544; called by muse, mutect2, varscan2
- COPE | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV53229585; called by muse, mutect2, varscan2
- CROCC | c.1276A>G p.K426E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.325); catalogued as COSV65010167; called by muse, mutect2, varscan2
- FAM160B2 | c.1073C>G p.T358R | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV57157051; called by muse, mutect2, varscan2
- FIGNL1 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs771236637, COSV63553224; called by muse, mutect2, varscan2
- GALNT17 | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as rs1025862050, COSV61148844; called by muse, mutect2, varscan2
- HHIPL2 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58563283; called by muse, mutect2, varscan2
- INTS6 | c.2225C>A p.A742D | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV60876410; called by muse, mutect2, varscan2
- KCNA2 | c.1239C>G p.F413L | Missense Mutation (SNP) | VAF 86/322 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60369164; called by muse, mutect2, varscan2
- MEIOC | c.2236A>C p.T746P | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs746206047; called by mutect2, varscan2
- NELL2 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100421185, COSV61569528; called by muse, mutect2, varscan2
- NGEF | c.1140G>A p.L380= | Splice Region (SNP) | VAF 8/139 reads (6%) | catalogued as COSV50914596; called by muse, mutect2
- NRG3 | c.2105G>A p.R702Q (on ENST00000404547 / NM_001370084.1; = p.R678Q on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.053); catalogued as rs763500458, COSV64545779; called by muse, mutect2, varscan2
- OR2L8 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 161/715 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV61725673; called by muse, mutect2, varscan2
- PBXIP1 | c.1553A>C p.K518T | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV63776836; called by muse, mutect2
- PHAX | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV52550003; called by muse, mutect2, varscan2
- PMP2 | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 56/1032 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV56266699; called by muse, mutect2
- PTPN5 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs200523801, COSV100659731; called by muse, mutect2, varscan2
- RELN | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 28/703 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV58986848, COSV59009383; called by muse, mutect2
- RFC1 | c.2653G>A p.V885I (on ENST00000381897 / NM_001363496.2; = p.V884I on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs140065280, COSV62898440; called by muse, mutect2, varscan2
- RGL2 | c.2194C>A p.Q732K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65841954, COSV65842774; called by muse, mutect2, varscan2
- RPL11 | c.448A>T p.I150F (on ENST00000374550 / NM_001199802.1; = p.I151F on NM_000975.5) | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV65778303, COSV65778383; called by muse, mutect2, varscan2
- SLF2 | c.1544C>G p.S515C | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53271000; called by muse, mutect2, varscan2
- SUOX | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1160840061, COSV56266836, COSV56269673; called by muse, varscan2
- TBCD | c.1134G>A p.W378* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as rs767747027, COSV62797855; called by muse, mutect2, varscan2
- TENT2 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57134712; called by muse, mutect2, varscan2
- TEX15 | c.10G>T p.D4Y (on ENST00000256246; = p.D387Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV56341914; called by muse, mutect2, varscan2
- THEMIS | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV64069342; called by muse, mutect2
- TKTL2 | c.1267del p.V423Yfs*16 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as COSV54917334; called by mutect2, pindel, varscan2
- TLE1 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64719177, COSV64719375; called by muse, mutect2, varscan2
- TRIM62 | c.1315T>C p.Y439H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.999); catalogued as COSV52220425; called by muse, mutect2, varscan2
- TRPS1 | c.3827dup p.N1276Kfs*5 (on ENST00000220888 / NM_001330599.2; = p.N1289Kfs*5 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 48/417 reads (12%) | catalogued as rs1401148397; called by mutect2, varscan2
- USP51 | c.1088G>C p.R363T | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72351491; called by muse, mutect2, varscan2
- WFIKKN2 | c.1546C>G p.P516A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60957863; called by muse, mutect2, varscan2
- ZFAND2B | c.475A>G p.S159G | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54693125; called by muse, mutect2, varscan2
- ZNF318 | c.6737G>A p.R2246K | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); catalogued as COSV58930358; called by muse, mutect2, varscan2
- ZNF479 | c.553T>A p.F185I | Missense Mutation (SNP) | VAF 115/410 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV58636051; called by muse, mutect2, varscan2
- ZNF608 | c.2091G>A p.M697I | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.805); catalogued as COSV60435463; called by muse, mutect2, varscan2
- AFF3 | c.1418del p.N473Tfs*11 | Frame Shift Del (DEL) | VAF 56/223 reads (25%) | called by mutect2, pindel, varscan2
- CERK | c.748_778del p.G250Ifs*57 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- CLIC5 | c.954_955del p.E318Dfs*2 (on ENST00000185206 / NM_001370649.1; = p.E159Dfs*2 on NM_016929.5) | Frame Shift Del (DEL) | VAF 59/280 reads (21%) | called by pindel, varscan2
- MAN1A1 | c.1168del p.Y390Ifs*5 | Frame Shift Del (DEL) | VAF 220/997 reads (22%) | called by mutect2, pindel, varscan2
- MCOLN1 | c.1715_1725del p.S572Ffs*32 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- MCOLN3 | c.1367del p.N456Mfs*18 | Frame Shift Del (DEL) | VAF 70/264 reads (27%) | called by mutect2, pindel, varscan2
- SPA17 | c.313-16_319del p.X105_splice | Splice Site (DEL) | VAF 30/162 reads (19%) | called by mutect2, pindel
- WDR33 | c.1488del p.Y496* | Frame Shift Del (DEL) | VAF 189/768 reads (25%) | called by mutect2, pindel, varscan2
- ZNF92 | c.1540del p.C514Vfs*16 (on ENST00000328747 / NM_152626.4; = p.C445Vfs*16 on NM_007139.4) | Frame Shift Del (DEL) | VAF 44/159 reads (28%) | called by mutect2, pindel, varscan2
- C22orf31 | c.420A>G p.G140= | Silent (SNP) | VAF 61/228 reads (27%) | catalogued as COSV53310108; called by muse, mutect2, varscan2
- CDV3 | c.399T>C p.G133= | Silent (SNP) | VAF 136/545 reads (25%) | catalogued as rs773492515, COSV53911452; called by muse, varscan2
- CFTR | c.3159T>G p.T1053= | Silent (SNP) | VAF 38/408 reads (9%) | catalogued as COSV50041555; called by muse, mutect2
- DEFB114 | c.153C>A p.S51= | Silent (SNP) | VAF 97/367 reads (26%) | catalogued as COSV59037168; called by muse, mutect2, varscan2
- HEATR5A | c.2757C>T p.A919= | Silent (SNP) | VAF 65/244 reads (27%) | catalogued as COSV66338628; called by muse, mutect2, varscan2
- HJURP | c.1641T>C p.N547= | Silent (SNP) | VAF 46/459 reads (10%) | catalogued as COSV64978502; called by muse, mutect2, varscan2
- JADE3 | c.579A>C p.L193= | Silent (SNP) | VAF 54/667 reads (8%) | catalogued as COSV54464396; called by muse, mutect2
- JPH2 | c.858C>T p.T286= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV65901886; called by muse, mutect2
- LSM1 | c.168C>T p.Y56= | Silent (SNP) | VAF 42/563 reads (7%) | catalogued as rs769909686, COSV60948511; called by muse, mutect2
- LTBP1 | c.3486C>T p.I1162= (on ENST00000404816 / NM_206943.4; = p.I836= on NM_000627.4) | Silent (SNP) | VAF 97/361 reads (27%) | catalogued as COSV55375778, COSV99698079; called by muse, mutect2, varscan2
- NCOR1 | c.6411A>C p.P2137= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV51962016; called by muse, mutect2, varscan2
- NLRP12 | c.1587C>T p.D529= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs781712648, COSV60743835, COSV60758270; called by muse, mutect2, varscan2
- NXPE4 | c.1155G>T p.V385= (on ENST00000375478 / NM_001077639.2; = p.V101= on NM_017678.3) | Silent (SNP) | VAF 98/308 reads (32%) | catalogued as COSV64943420; called by muse, mutect2, varscan2
- PDZD2 | c.6243C>T p.S2081= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs1353542220, COSV56851363; called by muse, mutect2, varscan2
- PIAS4 | c.231G>A p.P77= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs757949859, COSV53678313; called by muse, mutect2, varscan2
- SPTY2D1 | c.1689A>C p.L563= | Silent (SNP) | VAF 73/247 reads (30%) | catalogued as rs759937458, COSV60472967; called by muse, mutect2, varscan2
- TTN | c.42769C>A p.R14257= (on ENST00000591111; = p.R6833= on NM_003319.4) | Silent (SNP) | VAF 24/444 reads (5%) | catalogued as CM1514720, COSV59899605, COSV60000160; called by muse, mutect2
- DST | c.4296+4357_4296+4358del | Intron (DEL) | VAF 25/128 reads (20%) | called by pindel, varscan2
